MMRF case MMRF_1977 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/60fe51de-8ece-4f0d-a665-cc8140a6ab89

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 45 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 45.4 years (16,572 days); ISS stage: III; Days to last known disease status: 997 days (2.7 years); Days to last follow up: 997 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 365 days (1.0 years); Days to treatment end: 365 days (1.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 7.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8961 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.84 mg/dL; Immunoglobulin G 18.6 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 11.2 µg/mL; Hemoglobin 5.33 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 309 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 8.5 g/dL; Glucose 6.49 mmol/L.
- Day 92 (ECOG 0): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.45 mg/dL; Immunoglobulin G 7.56 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.55 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 9 ×10⁹/L; Platelets 278 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 5.45 mmol/L.
- Day 175 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.79 mg/dL; Immunoglobulin G 6.93 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.86 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 7.7 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.39 mmol/L.
- Day 259: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.11 mg/dL; Immunoglobulin G 8.22 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 0.91 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 7.3 ×10⁹/L; Platelets 297 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 5.01 mmol/L.
- Day 353 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.89 mg/dL; Immunoglobulin G 8.97 g/L; Immunoglobulin A 1.48 g/L; Immunoglobulin M 0.93 g/L; Lactate Dehydrogenase 17.5 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 1.56 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 7.6 g/dL; Glucose 5.06 mmol/L.
- Day 449 (ECOG 1): Hemoglobin 7.5 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.22 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 5.39 mmol/L.
- Day 536 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.54 mg/dL; Immunoglobulin G 9.22 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 7.3 µg/mL; Hemoglobin 6.39 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.31 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.34 mmol/L.
- Day 624: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.43 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 1.91 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 9.2 µg/mL; Hemoglobin 6.39 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.87 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 7.4 g/dL; Glucose 3.91 mmol/L.
- Day 715 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.74 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 2.24 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.75 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 7.7 g/dL; Glucose 3.85 mmol/L.
- Day 829 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.76 mg/dL; Hemoglobin 6.76 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 7.37 mmol/L.
- Day 913 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Hemoglobin 6.51 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.25 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 4.9 mmol/L.
- Day 997 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.91 mg/dL; Hemoglobin 6.88 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.68 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 7.5 g/dL; Glucose 4.4 mmol/L.

Other clinical attributes
- Day 1: Weight: 67 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1977_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1977_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
